Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A3HD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A3HD-01B (Primary Tumor).

Sent :

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED] (Age: [REDACTED])

Service: Gynecology
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

UTERINE CERVIX, 10 O'CLOCK, BIOPSY
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, SEE COMMENT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By: [REDACTED]

Microscopic Description and Comment:

Squamous carcinoma in-situ is noted in the overlying epithelium. There is no lymphovascular space invasion identified.

M.D.

History:

The patient is a [REDACTED] year old woman with no clinical history provided. Operative procedure and findings: Cervical biopsy at 10 o'clock.

Specimen(s) Received:

A: CERVIX AT 10 O'CLOCK

Gross Description

The specimen is received in a single formalin-filled container labeled [REDACTED] and the patient's information." It contains four irregular grey-white tissue fragments ranging in size from 0.4 to 0.2 cm. Labeled A1. Jar 0.

This Surgical Pathology report is available on-line on [REDACTED] and Clinical Desktop.

The pathologist's electronic signature is displayed on this report. The pathologist's signature is a digital signature that is created by the pathologist's computer and is unique to the pathologist. The pathologist's signature is a digital signature that is created by the pathologist's computer and is unique to the pathologist. The pathologist's signature is a digital signature that is created by the pathologist's computer and is unique to the pathologist.

This report is generated by the TCGA Data Coordination Center (DCC) and is not to be used for clinical purposes. It is a copy of the report as it appears in the TCGA Data Coordination Center (DCC) and is not to be used for clinical purposes.

END OF REPORT

Page 1 of 1

1C5-0-3
Cervix, Squamous cell, NOS 807013
Site: Cervix, NOS C53.9 Jan 12/5/11

Source: NCI Genomic Data Commons file 22e43ca6-7714-4b36-b9c7-1311391b1c13 (TCGA-C5-A3HD.FF901048-0C46-4347-8826-ADEB000EC270.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).